Somatic mutation profile of tumor specimen TCGA-AN-A0FS-01A (aliquot TCGA-AN-A0FS-01A-11W-A050-09) from TCGA case TCGA-AN-A0FS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.7 years (20,352 days).
Specimen TCGA-AN-A0FS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 624c2427-81c7-454e-a710-07cd0d936ff4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FS-10A (Blood Derived Normal), aliquot TCGA-AN-A0FS-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c66609b-77ff-4e91-972f-95fcd38b0f0b

The open-access MAF lists 71 somatic variants for this specimen: 47 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 22, Nonsense Mutation 5, Frame Shift Ins 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPK | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as rs1554698878, COSV100698968; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA6 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV99446297; called by muse, mutect2, varscan2
- ADAM10 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53053820, COSV53054844; called by muse, mutect2
- AP2S1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV99617391; called by muse, mutect2
- ARHGAP31 | c.3122C>A p.A1041E | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.348); catalogued as COSV99956980; called by muse, mutect2
- CCDC136 | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52803405; called by muse, mutect2, varscan2
- CCL11 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as rs779102512, COSV59925520; called by muse, mutect2, varscan2
- CD3G | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52675822; called by muse, mutect2, varscan2
- CDH16 | c.2432C>A p.S811* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100233821; called by muse, mutect2
- CGA | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV100851689; called by muse, mutect2
- COL14A1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52864320; called by muse, mutect2, varscan2
- CRIM1 | c.1595G>T p.C532F | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99753146; called by muse, mutect2
- CTCF | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV50499440; called by muse, mutect2, varscan2
- DNAH3 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769073354, COSV54537817; called by muse, mutect2, varscan2
- FAM189A2 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99974965; called by muse, mutect2
- FAM98A | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV53208728, COSV99479224; called by muse, mutect2
- FMO2 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 12/336 reads (4%) | catalogued as COSV99269074; called by muse, mutect2
- GAS7 | c.848C>T p.A283V (on ENST00000432992 / NM_201433.2; = p.A143V on NM_003644.3) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.489); catalogued as rs779042022, COSV60436509; called by muse, mutect2, varscan2
- GPR155 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55041043; called by muse, mutect2, varscan2
- HDAC4 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV61862524, COSV61873113; called by muse, mutect2, varscan2
- HMCN1 | c.14254G>A p.D4752N | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV54873757, COSV99628052; called by muse, mutect2
- IPO9 | c.1388A>C p.D463A | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs970624247, COSV100843400; called by muse, mutect2
- KRI1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 158/208 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs752490810, COSV57265541; called by muse, mutect2, varscan2
- LAMC3 | c.3040C>T p.P1014S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1311308049, COSV63093310; called by muse, mutect2
- LRRCC1 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV100835402; called by muse, mutect2
- MAP1A | c.6497C>A p.S2166* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV55811517; called by muse, mutect2, varscan2
- MPHOSPH10 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.883); catalogued as COSV54906726; called by muse, mutect2, varscan2
- MTMR7 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51669371; called by muse, mutect2, varscan2
- NHS | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs745597127, COSV66278595; called by muse, mutect2, varscan2
- NINL | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54007149; called by muse, mutect2, varscan2
- PIWIL1 | c.2491C>G p.P831A | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55349384, COSV55350478; called by muse, mutect2, varscan2
- RPTOR | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV100155978; called by muse, mutect2
- RTF1 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 24/491 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101047778; called by muse, mutect2
- SAT1 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV63380767; called by muse, mutect2, varscan2
- SDR9C7 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs150520393, COSV53290314; called by muse, mutect2, varscan2
- SNAP25 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99654785; called by muse, mutect2
- SNX19 | c.2084C>G p.S695C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375635584; called by muse, mutect2
- SOX10 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as CM147056, COSV100329724; called by muse, mutect2
- SSH3 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 97/131 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100354525; called by muse, mutect2, varscan2
- TENM2 | c.3823C>T p.R1275* (on ENST00000518659 / NM_001122679.2; = p.R1043C on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as rs751325623, COSV69128433; called by muse, mutect2, varscan2
- TIRAP | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs370756926, COSV67024560; called by muse, mutect2, varscan2
- TRPV6 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63893109; called by muse, mutect2, varscan2
- TXLNG | c.427A>T p.M143L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as COSV66330350; called by muse, mutect2, varscan2
- VNN1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV63390131, COSV63390671; called by muse, varscan2
- LPGAT1 | c.697_698dup p.S233Rfs*11 | Frame Shift Ins (INS) | VAF 57/123 reads (46%) | called by mutect2, pindel, varscan2
- TBX3 | c.868dup p.T290Nfs*37 (on ENST00000257566 / NM_016569.4; = p.T270Nfs*37 on NM_005996.4) | Frame Shift Ins (INS) | VAF 38/107 reads (36%) | called by mutect2, varscan2
- ARHGAP17 | c.618G>C p.G206= | Silent (SNP) | VAF 55/207 reads (27%) | catalogued as COSV51510776; called by muse, mutect2, varscan2
- ATP2B3 | c.2427C>T p.F809= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs782242880, COSV54857600; called by muse, mutect2, varscan2
- CACNA1G | c.384T>C p.F128= | Silent (SNP) | VAF 43/263 reads (16%) | catalogued as COSV61735167; called by muse, mutect2, varscan2
- ENTPD6 | c.684G>A p.A228= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs756988234, COSV61752177; called by muse, mutect2, varscan2
- EPHA3 | c.1140C>T p.V380= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs898186136, COSV60720465; called by muse, mutect2, varscan2
- GIMAP1 | c.771C>T p.G257= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs762097392, COSV100212090; called by muse, mutect2
- IGHV1-18 | c.169C>A p.R57= | Silent (SNP) | VAF 71/204 reads (35%) | called by muse, mutect2, varscan2
- IGSF22 | c.1842G>A p.A614= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs377071364, COSV60039939; called by muse, mutect2, varscan2
- KLHL22 | c.1527G>A p.R509= | Silent (SNP) | VAF 168/255 reads (66%) | catalogued as rs1035058624, COSV61022409; called by muse, mutect2, varscan2
- KRTAP4-3 | c.153G>A p.R51= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV66940968; called by muse, varscan2
- M1AP | c.486G>A p.L162= | Silent (SNP) | VAF 6/168 reads (4%) | catalogued as COSV99303968, COSV99304118; called by muse, mutect2
- MAN1A2 | c.55C>T p.L19= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV62980392; called by muse, mutect2, varscan2
- MYH13 | c.2418G>A p.K806= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV52838564; called by muse, mutect2, varscan2
- PKD2L1 | c.138C>T p.L46= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV100559359, COSV100559453; called by muse, mutect2
- PKN1 | c.1677G>A p.S559= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs778135263, COSV54394715; called by muse, mutect2, varscan2
- PROX2 | c.1635C>T p.A545= (on ENST00000556489 / NM_001243007.1; = p.A318= on NM_001080408.2) | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV71520141; called by muse, mutect2, varscan2
- SACM1L | c.987A>G p.G329= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV101203762; called by muse, mutect2
- SCN8A | c.312C>T p.F104= | Silent (SNP) | VAF 16/322 reads (5%) | catalogued as COSV100633711; called by muse, mutect2
- SLC25A31 | c.258T>C p.N86= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as rs766982375, COSV55420788; called by muse, mutect2, varscan2
- SPANXN3 | c.343C>T p.L115= | Silent (SNP) | VAF 30/506 reads (6%) | catalogued as COSV100980790; called by muse, mutect2
- TRAV39 | c.144C>T p.D48= | Silent (SNP) | VAF 34/342 reads (10%) | called by muse, mutect2
- ZBTB21 | c.1242G>A p.Q414= | Silent (SNP) | VAF 83/158 reads (53%) | catalogued as rs139126603; called by muse, mutect2, varscan2
- ANKRD20A5P | n.368G>A | RNA (SNP) | VAF 32/66 reads (48%) | catalogued as rs1248868875; called by muse, mutect2, varscan2
- TMEM183B | n.807C>T | RNA (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
